Somatic mutation profile of tumor specimen 0DKGXG from CCDI case PBBVYU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Sphenoid sinus; Age at diagnosis: 8.7 years (3,178 days).
Specimen 0DKGXG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fff3747-c802-4219-9177-e7cd688c39e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKGX7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbf7e6bd-01bf-4790-968c-e0228ef1855c

The open-access MAF lists 68 somatic variants for this specimen: 45 protein-altering or splice-affecting, 8 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 8, Intron 6, Nonsense Mutation 6, 3'UTR 5, 5'UTR 2, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 805/1080 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774571806, COSV52800715, COSV52802492, COSV52804538; called by muse, varscan2
- AMACR | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 309/1037 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201507169, COSV56871888; called by muse, mutect2, varscan2
- BTBD8 | c.3223G>C p.V1075L (on ENST00000636805 / NM_001376131.1; = p.V562L on NM_015237.4) | Missense Mutation (SNP) | VAF 590/1264 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV64883873; called by muse, mutect2, varscan2
- CARD14 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 189/427 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs200731780, CM161583; called by muse, mutect2, varscan2
- CSMD1 | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 396/1786 reads (22%) | catalogued as rs1454618195; called by muse, mutect2, varscan2
- DNAH12 | c.7261C>T p.R2421* (on ENST00000351747; = p.R3289* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 271/675 reads (40%) | catalogued as rs1289708280; called by muse, mutect2, varscan2
- FOXI3 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 237/825 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.065); catalogued as COSV67916842; called by muse, mutect2, varscan2
- GREM2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV58946484; called by muse, mutect2, varscan2
- MUC2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 208/723 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs750847605; called by muse, mutect2, varscan2
- NCOR2 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 74/535 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs371727103; called by muse, mutect2, varscan2
- NKX2-4 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 382/914 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs1240726775; called by muse, varscan2
- NPBWR1 | c.6C>G p.D2E | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1197114866; called by muse, mutect2, varscan2
- P2RX4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 102/572 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778944606; called by muse, mutect2, varscan2
- PDE8B | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 248/807 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53737973; called by muse, mutect2, varscan2
- RAG1 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 428/1520 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55027598; called by muse, mutect2, varscan2
- SCN1A | c.5455G>T p.A1819S (on ENST00000303395 / NM_001202435.3; = p.A1808S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 418/1352 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99066798; called by muse, mutect2, varscan2
- SHOX2 | c.480C>G p.D160E (on ENST00000441443 / NM_006884.3; = p.D184E on NM_003030.4) | Missense Mutation (SNP) | VAF 269/639 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.693); catalogued as rs1196251037, COSV101273780; called by muse, mutect2, varscan2
- SIN3A | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 189/487 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV100845033; called by muse, mutect2, varscan2
- SLC22A13 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 227/610 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs781014948; called by muse, mutect2, varscan2
- SNTG1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 819/3422 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769991462, COSV52435349; called by muse, mutect2, varscan2
- SPEF2 | c.1019G>C p.R340P | Missense Mutation (SNP) | VAF 407/1355 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99214207, COSV99214224; called by muse, mutect2, varscan2
- SRSF7 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 323/1179 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as rs1180480328; called by muse, mutect2, varscan2
- TDRD1 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 412/1006 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99314679; called by muse, varscan2
- TICRR | c.5450C>T p.T1817M | Missense Mutation (SNP) | VAF 151/351 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs780264569, COSV99176032; called by muse, mutect2, varscan2
- U2SURP | c.1945C>G p.R649G | Missense Mutation (SNP) | VAF 425/1085 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1172660838; called by muse, mutect2, varscan2
- ARRDC2 | c.611_612del p.F204Cfs*133 | Frame Shift Del (DEL) | VAF 96/253 reads (38%) | called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 32/1058 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CNTNAP3B | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 214/1024 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- FAXC | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 273/554 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 56/1666 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- NELL2 | c.1230T>A p.N410K | Missense Mutation (SNP) | VAF 497/2510 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NUP160 | c.2646G>C p.L882F | Missense Mutation (SNP) | VAF 149/625 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NYAP1 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- OR14I1 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 228/1034 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PABPC5 | c.738T>G p.Y246* | Nonsense Mutation (SNP) | VAF 390/432 reads (90%) | called by muse, mutect2, varscan2
- PKP2 | c.680G>C p.S227T | Missense Mutation (SNP) | VAF 94/653 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASIP1 | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 121/368 reads (33%) | called by muse, mutect2, varscan2
- RB1CC1 | c.3867_3870dup p.L1291* | Nonsense Mutation (INS) | VAF 400/2052 reads (19%) | called by mutect2, varscan2
- RNF19A | c.1391C>A p.A464E | Missense Mutation (SNP) | VAF 477/2228 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, varscan2
- SLC4A11 | c.1123dup p.Y375Lfs*24 | Frame Shift Ins (INS) | VAF 174/825 reads (21%) | called by mutect2, varscan2
- SPOCK3 | c.651C>G p.F217L | Missense Mutation (SNP) | VAF 546/1308 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TET3 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 71/332 reads (21%) | called by muse, mutect2, varscan2
- TTC1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 610/1079 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBE2K | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 256/597 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- VEGFD | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 252/292 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GIGYF2 | c.1575G>A p.S525= | Silent (SNP) | VAF 782/1292 reads (61%) | catalogued as rs370762713; called by muse, mutect2, varscan2
- GRID2 | c.1032C>T p.D344= | Silent (SNP) | VAF 416/1002 reads (42%) | called by muse, mutect2, varscan2
- KEL | c.1488C>T p.N496= | Silent (SNP) | VAF 300/519 reads (58%) | catalogued as rs139823086; called by muse, mutect2, varscan2
- LRRC14 | c.258G>A p.Q86= | Silent (SNP) | VAF 196/891 reads (22%) | catalogued as rs1564818029; called by muse, mutect2, varscan2
- NELL2 | c.174T>C p.F58= | Silent (SNP) | VAF 380/1054 reads (36%) | called by muse, mutect2, varscan2
- NOTCH2 | c.6900C>T p.P2300= | Silent (SNP) | VAF 122/320 reads (38%) | catalogued as rs757902354; called by muse, mutect2, varscan2
- RALYL | c.804A>G p.E268= | Silent (SNP) | VAF 351/1778 reads (20%) | called by muse, mutect2, varscan2
- TIAM1 | c.1314C>T p.G438= | Silent (SNP) | VAF 222/572 reads (39%) | catalogued as COSV99733176; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 26/799 reads (3%) | called by muse, mutect2
- CIT | c.4558+68G>C | Intron (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- CNP | c.*2715G>A | 3'UTR (SNP) | VAF 127/280 reads (45%) | catalogued as rs577962906; called by muse, mutect2, varscan2
- KCNJ18 | c.*84C>T | 3'UTR (SNP) | VAF 44/103 reads (43%) | catalogued as rs1451232398; called by muse, mutect2, varscan2
- NR2C1 | c.966-41G>A | Intron (SNP) | VAF 102/294 reads (35%) | catalogued as rs375402403; called by muse, mutect2, varscan2
- NUP107 | c.1999-58T>C | Intron (SNP) | VAF 81/381 reads (21%) | called by muse, mutect2, varscan2
- OPRK1 | c.-7C>T | 5'UTR (SNP) | VAF 141/567 reads (25%) | called by muse, mutect2, varscan2
- PDE4A | chr19:10417861 G>A | 5'Flank (SNP) | VAF 212/475 reads (45%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 42/361 reads (12%) | called by muse, varscan2
- SCRIB | chr8:143815464 G>T | 5'Flank (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- SERTAD4 | c.*3664T>C | 3'UTR (SNP) | VAF 81/433 reads (19%) | called by muse, mutect2, varscan2
- SLA | c.-319+43C>A | Intron (SNP) | VAF 133/503 reads (26%) | called by muse, mutect2, varscan2
- SLC25A44 | c.626-22A>G | Intron (SNP) | VAF 112/420 reads (27%) | catalogued as rs770992105; called by muse, mutect2, varscan2
- SSTR3 | c.*86C>A | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- TBC1D7 | c.381+82C>T | Intron (SNP) | VAF 432/975 reads (44%) | called by muse, mutect2, varscan2
